Gene-level copy-number profile of tumor specimen TCGA-2G-AAH2-01A from TCGA case TCGA-2G-AAH2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 20.9 years (7,635 days).
Specimen TCGA-2G-AAH2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.f1598631-a64f-41c1-b06c-d2235a21e2d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAH2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75d32a99-9303-4a22-9cbf-e95a84895d74

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 24,684; copy number 3: 28,812; copy number 4: 2,300; copy number 5: 2,485; copy number 7: 636; copy number 8: 44; copy number 9: 851.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAH2-01A-11D-A42X-01): tumor purity 0.77, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,531 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–37,576,384, 851 genes, copy number 9 (broad region; genes not listed).
- chr16:46,469,341–70,801,160, 629 genes, copy number 7–8 (broad region; genes not listed).
- chr16:71,281,389–72,665,014, 50 genes, copy number 7: CMTR2, AC106736.1, CALB2, LINC02136, AC010547.6, TLE7, AC010547.5, ZNF23, AC010547.4, AC010547.1, ZNF19, AC010547.3, CHST4, AC010547.2, RNU6-1061P, TAT-AS1, TAT, AC009097.2, MARVELD3, PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3, AC010653.1, ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1, PKD1L3, RPL39P31, AC009127.2, ATP5F1AP3, DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38, PMFBP1, AC009075.1, LINC01572, AC009075.2, U6, AC004158.1.
- chr16:72,673,503–72,673,564, 1 gene, copy number 7: RNU7-90P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
